Somatic mutation profile of tumor specimen ALCH-AEFM-TTP1-A (aliquot ALCH-AEFM-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEFM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,826 days).
Specimen ALCH-AEFM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0604ecc1-d266-45e4-a5a0-506bc7442f50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEFM-NB1-A (Blood Derived Normal), aliquot ALCH-AEFM-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c47d1dd-4eb6-4524-9baa-170a042c7389

The open-access MAF lists 104 somatic variants for this specimen: 75 protein-altering or splice-affecting, 18 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 18, Intron 7, Nonsense Mutation 3, Splice Site 2, 3'UTR 2, Frame Shift Del 1, 3'Flank 1, RNA 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1572G>T p.W524C | Missense Mutation (SNP) | VAF 80/369 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV61685820, COSV61686227, COSV61686374; called by muse, mutect2, varscan2
- ARFGAP1 | c.203A>T p.K68M | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62263610; called by muse, mutect2, varscan2
- ATAD2 | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99785510; called by muse, mutect2
- BRPF3 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV60206753; called by muse, mutect2
- C1orf112 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 88/571 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376471585; called by muse, mutect2, varscan2
- CNOT9 | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 30/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55300458; called by muse, mutect2
- COL2A1 | c.4376G>A p.R1459H | Missense Mutation (SNP) | VAF 190/1542 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs777416478, COSV99873421; called by muse, mutect2, varscan2
- COL6A6 | c.5491A>G p.I1831V | Missense Mutation (SNP) | VAF 46/770 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1451855284; called by muse, mutect2
- CUBN | c.9232C>A p.L3078I | Missense Mutation (SNP) | VAF 20/547 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100913415; called by muse, mutect2
- DCDC1 | c.5282G>A p.G1761D (on ENST00000597505 / NM_001367979.1; = p.G868D on NM_020869.3) | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV57999330; called by muse, mutect2, varscan2
- ENDOV | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs748840023; called by muse, mutect2, varscan2
- EQTN | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs960033523; called by muse, mutect2
- GNE | c.1324G>A p.A442T (on ENST00000396594 / NM_001128227.3; = p.A411T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/666 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.116); catalogued as COSV64951253; called by muse, mutect2, varscan2
- GOLIM4 | c.737G>A p.S246N | Missense Mutation (SNP) | VAF 53/734 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1183624572; called by muse, mutect2
- IQCA1 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 85/423 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs765152475, COSV54498921; called by muse, mutect2, varscan2
- KLC3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1398837710; called by muse, mutect2, varscan2
- MAGED2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.593); catalogued as rs779634966, COSV54497890; called by muse, mutect2, varscan2
- MCCC1 | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM147493; called by muse, mutect2
- MTREX | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV57929009; called by muse, mutect2, varscan2
- MYCN | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1216742855, COSV55257421; called by muse, mutect2
- NUP98 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 38/718 reads (5%) | catalogued as rs770056961, COSV61428786; called by muse, mutect2
- PLXNA1 | c.2105T>C p.V702A | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.036); catalogued as COSV52529552; called by muse, mutect2
- PTPRC | c.700A>G p.N234D | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs535416574; ClinVar: uncertain significance; called by muse, mutect2
- SEZ6 | c.1515C>A p.F505L | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV57979557; called by muse, mutect2
- SFSWAP | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55526473; called by muse, mutect2, varscan2
- SMARCAD1 | c.1808+1G>T p.X603_splice | Splice Site (SNP) | VAF 60/618 reads (10%) | catalogued as COSV62774968; called by muse, mutect2
- SNX8 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 56/448 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1223707276; called by muse, mutect2, varscan2
- TIE1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs570803002; called by muse, mutect2, varscan2
- ABTB1 | c.411T>G p.S137R | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACOT9 | c.1135T>A p.S379T | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.281); called by muse, mutect2
- ADAMTS13 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 78/666 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AP4E1 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); called by muse, mutect2
- APP | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 43/847 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.576); called by muse, mutect2
- BEND5 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.935); called by muse, mutect2
- CCN5 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CDHR5 | c.2312T>C p.I771T (on ENST00000358353 / NM_001171968.2; = p.I777T on NM_021924.5) | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CENPI | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- CMYA5 | c.1327C>G p.L443V | Missense Mutation (SNP) | VAF 26/479 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2
- DHX57 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 104/484 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM171A1 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- FAM53C | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 30/871 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- FLG2 | c.6392C>A p.S2131Y | Missense Mutation (SNP) | VAF 71/462 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FLNA | c.1649A>G p.Y550C | Missense Mutation (SNP) | VAF 85/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMR1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 42/680 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2
- GPATCH8 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRIG3 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 60/742 reads (8%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAP4K4 | c.2224C>G p.L742V (on ENST00000347699 / NM_001242559.2; = p.L660V on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/554 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MET | c.1571A>G p.Q524R | Missense Mutation (SNP) | VAF 54/633 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2
- MIB1 | c.399G>A p.E133= | Splice Region (SNP) | VAF 22/335 reads (7%) | called by muse, mutect2
- MYH9 | c.4207_4209del p.E1403del | In Frame Del (DEL) | VAF 32/327 reads (10%) | called by pindel, varscan2
- MYO7B | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 34/700 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.135); called by muse, mutect2
- NBEAL2 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NFYB | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 46/731 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR1N1 | c.185C>G p.A62G | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR52B6 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- OSBPL3 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PITPNM2 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 87/394 reads (22%) | called by muse, mutect2, varscan2
- POLRMT | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- RBFA | c.354T>A p.Y118* | Nonsense Mutation (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- SETD2 | c.2649del p.Q884Rfs*7 | Frame Shift Del (DEL) | VAF 37/165 reads (22%) | called by mutect2, pindel, varscan2
- SLC9A8 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- SMO | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- SPDL1 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SPECC1L | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 65/658 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SRCIN1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SREBF1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- SWT1 | c.2375A>T p.E792V | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM72 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TTC27 | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- VPS45 | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WDR97 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- WDTC1 | c.1643+1G>T p.X548_splice (on ENST00000319394 / NM_001276252.2; = p.X547_splice on NM_015023.5) | Splice Site (SNP) | VAF 50/571 reads (9%) | called by muse, mutect2
- ZC3H12B | c.213G>C p.E71D | Missense Mutation (SNP) | VAF 19/488 reads (4%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2
- ZNF20 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 31/353 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF397 | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADAMTS3 | c.1404C>A p.L468= | Silent (SNP) | VAF 134/451 reads (30%) | called by muse, mutect2, varscan2
- CAND1 | c.1923G>A p.K641= | Silent (SNP) | VAF 60/672 reads (9%) | catalogued as rs755563871; called by muse, mutect2
- CCNL1 | c.516G>A p.Q172= | Silent (SNP) | VAF 19/312 reads (6%) | called by muse, mutect2
- CD300LD | c.243C>A p.I81= | Silent (SNP) | VAF 30/444 reads (7%) | called by muse, mutect2
- COL5A1 | c.2181C>T p.G727= | Silent (SNP) | VAF 58/538 reads (11%) | catalogued as rs201298716, COSV65667559; called by muse, mutect2, varscan2
- EXOC7 | c.1284G>A p.T428= (on ENST00000335146 / NM_001145297.4; = p.T346= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/449 reads (17%) | catalogued as rs764394822, COSV58744708; called by muse, mutect2, varscan2
- FLNC | c.1998C>T p.F666= | Silent (SNP) | VAF 180/423 reads (43%) | catalogued as rs1322821191; called by muse, mutect2, varscan2
- GATD1 | c.240C>T p.S80= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as rs1252909206; called by muse, mutect2, varscan2
- KRT81 | c.261C>T p.L87= | Silent (SNP) | VAF 246/1094 reads (22%) | called by muse, varscan2
- MARK3 | c.1218G>A p.Q406= | Silent (SNP) | VAF 18/451 reads (4%) | catalogued as COSV53514949; called by muse, mutect2
- MYO3B | c.2976C>T p.G992= | Silent (SNP) | VAF 76/348 reads (22%) | called by muse, mutect2, varscan2
- NR2C2 | c.192G>A p.V64= (on ENST00000393102; = p.V83= on NM_003298.5) | Silent (SNP) | VAF 38/730 reads (5%) | called by muse, mutect2
- OR6N2 | c.939T>C p.S313= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1017111678, COSV59413504; called by muse, mutect2, varscan2
- SORT1 | c.54C>T p.L18= | Silent (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- THOP1 | c.1671C>T p.L557= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs751754428; called by muse, mutect2
- TNFSF4 | c.447C>G p.V149= | Silent (SNP) | VAF 40/518 reads (8%) | called by muse, mutect2
- TRPC7 | c.660C>T p.N220= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV61452104; called by muse, mutect2, varscan2
- ZNF510 | c.918G>A p.K306= | Silent (SNP) | VAF 24/510 reads (5%) | called by muse, mutect2
- AMDHD2 | c.*1032G>A | 3'UTR (SNP) | VAF 32/161 reads (20%) | catalogued as COSV99565972; called by muse, mutect2, varscan2
- CRYAB | c.325-31C>T | Intron (SNP) | VAF 35/329 reads (11%) | called by muse, mutect2, varscan2
- GTPBP2 | c.186+184C>T | Intron (SNP) | VAF 29/363 reads (8%) | called by muse, mutect2
- LGI4 | c.793+36G>A | Intron (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- MAGEC3 | c.910-553G>A | Intron (SNP) | VAF 63/399 reads (16%) | catalogued as COSV68924267; called by muse, mutect2, varscan2
- MKRN9P | n.372A>T | RNA (SNP) | VAF 337/942 reads (36%) | called by muse, mutect2, varscan2
- OTOF | c.*78C>T | 3'UTR (SNP) | VAF 117/632 reads (19%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157465 G>A | 3'Flank (SNP) | VAF 43/1150 reads (4%) | called by muse, mutect2
- SLC13A5 | c.369-187G>A | Intron (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- SMIM7 | c.122-1222G>C | Intron (SNP) | VAF 15/335 reads (4%) | called by muse, mutect2
- TBX22 | c.175+25C>A | Intron (SNP) | VAF 62/666 reads (9%) | called by muse, mutect2
